Somatic mutation profile of tumor specimen TCGA-CN-4741-01A (aliquot TCGA-CN-4741-01A-01D-1434-08) from TCGA case TCGA-CN-4741, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 75.3 years (27,506 days).
Specimen TCGA-CN-4741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0aa8cbc-ff03-491b-a0bc-081eab2c478a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4741-10A (Blood Derived Normal), aliquot TCGA-CN-4741-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44ff13ec-d02a-44df-beeb-76e99a661359

The open-access MAF lists 115 somatic variants for this specimen: 80 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 33, Nonsense Mutation 4, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 32/282 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RAG1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs104894289, CM981692, COSV100200812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1213G>A p.G405S (on ENST00000219054; = p.G326S on NM_001308169.2) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs570810199, COSV54582582; called by muse, mutect2, varscan2
- ACSS3 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747109152, COSV99698558, COSV99699436; called by muse, mutect2, varscan2
- ACTG2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as CM1514547, COSV100608985, COSV61829188; called by muse, mutect2, varscan2
- ADA2 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99375874; called by muse, mutect2, varscan2
- ADAM20 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs1203480210, COSV99833387, COSV99833648; called by muse, mutect2
- ALG10 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV99848032; called by muse, mutect2, varscan2
- ANO1 | c.1650G>T p.M550I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100303874; called by muse, mutect2, varscan2
- CAT | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573168; called by muse, mutect2
- CDH10 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050890; called by muse, mutect2, varscan2
- CDH9 | c.2039C>A p.P680Q | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50362848, COSV99142884; called by muse, mutect2
- CHRNB3 | c.665T>C p.F222S | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.903); catalogued as COSV99251044; called by muse, mutect2, varscan2
- CLEC3A | c.355G>T p.E119* (on ENST00000651443; = p.E110* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLN3 | c.316G>A p.V106I (on ENST00000360019 / NM_001286104.2; = p.V130I on NM_000086.2) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs764261700, COSV61104761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN2 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV71718074, COSV71720623; called by muse, mutect2, varscan2
- CPA2 | c.1244G>C p.R415P | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV55978600, COSV55979304; called by muse, mutect2, varscan2
- CTNND2 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs767934296, COSV58864210; called by muse, mutect2, varscan2
- CXXC1 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV53273034; called by muse, mutect2, varscan2
- DEFB114 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.439); catalogued as COSV59037101; called by muse, mutect2, varscan2
- DOCK7 | c.5493+1G>T p.X1831_splice (on ENST00000635253 / NM_001367561.1; = p.X1800_splice on NM_033407.3) | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as COSV51995349; called by muse, mutect2, varscan2
- EED | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646286; called by muse, mutect2
- EIF2AK4 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 26/417 reads (6%) | catalogued as COSV55470374, COSV99774422; called by muse, mutect2
- ELF1 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53496931; called by muse, mutect2, varscan2
- EPAS1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55383997; called by muse, mutect2, varscan2
- F2RL3 | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50185100; called by muse, mutect2, varscan2
- FAT4 | c.8942A>T p.N2981I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58670950; called by muse, mutect2, varscan2
- FBLIM1 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60028519; called by muse, varscan2
- FBLIM1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs776825526, COSV60028532; called by muse, varscan2
- GRIP1 | c.3358G>A p.E1120K (on ENST00000359742 / NM_001379345.1; = p.E1068K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs757132065, COSV99668945; called by muse, mutect2
- HCN4 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM073122, COSV56081161, COSV56081469; called by muse, mutect2, varscan2
- HTATSF1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV99511565; called by muse, mutect2
- INPP5F | c.2293C>G p.Q765E | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV100740072; called by muse, mutect2
- IRS4 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100929505; called by muse, mutect2
- JAKMIP3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355503004, COSV53819585; called by muse, mutect2, varscan2
- KMT2A | c.9409C>G p.P3137A | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100628504, COSV63292437; called by muse, mutect2
- KMT2D | c.3472G>T p.E1158* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as COSV56409640, COSV56428576; called by muse, mutect2, varscan2
- LRCH3 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV58388632; called by muse, mutect2, varscan2
- MAN2C1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs149884810; called by muse, mutect2, varscan2
- MAP9 | c.1455G>C p.K485N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100250821, COSV100250836; called by muse, mutect2
- MAP9 | c.494G>T p.S165I | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV60903544; called by muse, mutect2, varscan2
- MBD1 | c.1409C>T p.P470L (on ENST00000269468 / NM_001323950.1; = p.P414L on NM_002384.2) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199727558, COSV53997943; called by muse, mutect2, varscan2
- MEGF11 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754335032, COSV56544449; called by muse, mutect2, varscan2
- NBEA | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 33/234 reads (14%) | catalogued as rs1288199769, COSV59762270; called by muse, mutect2, varscan2
- NFATC3 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100285089; called by muse, mutect2
- NLRP1 | c.4152G>T p.Q1384H (on ENST00000572272 / NM_033004.4; = p.Q1340H on NM_014922.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52558193; called by muse, mutect2, varscan2
- NRG4 | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV67529781; called by muse, varscan2
- NRXN3 | c.456C>A p.F152L (on ENST00000557594 / NM_001272020.2; = p.F784L on NM_004796.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV55314097; called by muse, mutect2, varscan2
- PAPPA | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295411612, COSV60277244; called by muse, mutect2, varscan2
- PAXBP1 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51606663, COSV51610578; called by muse, mutect2, varscan2
- PCDHGA1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs769162898, COSV65294845; called by muse, mutect2, varscan2
- PLK3 | c.1783C>A p.L595I | Missense Mutation (SNP) | VAF 209/471 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.576); catalogued as COSV59499047; called by muse, mutect2, varscan2
- PLOD3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs761949569, COSV56181224; called by muse, mutect2, varscan2
- POFUT2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs771723355, COSV57957725; called by muse, mutect2, varscan2
- PRPF4B | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 127/158 reads (80%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.899); catalogued as rs1459522496, COSV61783232; called by muse, mutect2, varscan2
- PRPF4B | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV61783238; called by muse, mutect2, varscan2
- PTPRZ1 | c.4225G>T p.D1409Y | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.135); catalogued as COSV66429987; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3275A>T p.D1092V | Missense Mutation (SNP) | VAF 188/487 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.377); catalogued as COSV54758081; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV99769902; called by muse, mutect2
- RASSF9 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63432506; called by muse, mutect2, varscan2
- RGS22 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62657097; called by muse, mutect2, varscan2
- RIMS2 | c.1513G>A p.G505S (on ENST00000666250 / NM_001348490.2; = p.G313S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs200234707, COSV51700356; called by muse, mutect2, varscan2
- RUFY1 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60158287; called by muse, mutect2, varscan2
- SAMD9L | c.1158G>T p.M386I | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100560570; called by muse, mutect2
- SAMD9L | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs144605831; called by muse, mutect2
- SDHA | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs760542965, COSV53765307; called by muse, mutect2, varscan2
- SENP6 | c.1079G>C p.C360S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as COSV100519089; called by muse, mutect2, varscan2
- SFI1 | c.2462G>A p.R821Q (on ENST00000400288 / NM_001007467.3; = p.R790Q on NM_014775.4) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs764891956, COSV63475272; called by muse, mutect2, varscan2
- THSD7A | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs370952825; called by muse, mutect2, varscan2
- TRIM24 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58968885; called by muse, mutect2, varscan2
- TUBA3D | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs760601149, COSV58310728; called by muse, mutect2, varscan2
- UBE3A | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51660902; called by muse, mutect2, varscan2
- UBR4 | c.11933C>A p.S3978Y | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV64382680, COSV64387789; called by muse, mutect2, varscan2
- ZER1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99401947; called by muse, mutect2
- ZFP14 | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV54200874; called by muse, mutect2, varscan2
- ZNF16 | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99429566; called by muse, mutect2
- ZNF471 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1177564491, COSV57290947, COSV57292432; called by muse, mutect2, varscan2
- ZNF676 | c.1418G>A p.R473K (on ENST00000650058; = p.R441K on NM_001001411.3) | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.047); catalogued as COSV101236165, COSV68092102, COSV68092115; called by muse, varscan2
- ZNF711 | c.47G>T p.R16I | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV99340881, COSV99341539; called by muse, mutect2, varscan2
- NQO1 | c.520-2dup p.X174_splice | Splice Site (INS) | VAF 109/313 reads (35%) | called by mutect2, pindel, varscan2
- APBB2 | c.1233C>T p.N411= (on ENST00000295974 / NM_001166050.2; = p.N412= on NM_004307.2) | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV99922785; called by muse, mutect2, varscan2
- CCR2 | c.930G>A p.E310= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as COSV99432251; called by muse, mutect2
- CHST6 | c.759C>T p.A253= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1258970017, COSV59999398; called by muse, mutect2
- CSF2RA | c.513C>T p.D171= | Silent (SNP) | VAF 100/171 reads (58%) | catalogued as COSV62623404; called by muse, mutect2, varscan2
- DNAH1 | c.6297C>T p.I2099= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs377060183; called by muse, mutect2, varscan2
- DNAH17 | c.6612C>T p.D2204= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs376284980; called by muse, mutect2, varscan2
- DOT1L | c.1575C>T p.L525= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV67107853; called by muse, mutect2, varscan2
- IBTK | c.2178A>G p.K726= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV60390799; called by muse, mutect2, varscan2
- KCNN2 | c.508C>T p.L170= (on ENST00000264773; = p.L382= on NM_021614.4) | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV53282982; called by muse, mutect2, varscan2
- LRRIQ3 | c.1830G>A p.V610= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV63040963; called by muse, mutect2, varscan2
- MAML1 | c.2974C>T p.L992= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV52988730, COSV52988865; called by muse, mutect2
- MAN2A2 | c.1983C>T p.F661= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as COSV64637173; called by muse, mutect2
- MAP1S | c.3072C>T p.Y1024= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs1477138575, COSV60721552; called by muse, mutect2, varscan2
- MCU | c.990C>T p.D330= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs1387900904, COSV100849134; called by muse, mutect2, varscan2
- MYT1 | c.687C>T p.T229= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs751239715, COSV60500806; called by muse, mutect2
- NEURL1 | c.165C>T p.S55= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as rs757509316, COSV63913617; called by muse, mutect2, varscan2
- NLRP2 | c.1825C>T p.L609= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs903007408, COSV99672134; called by muse, mutect2
- PDHA2 | c.981C>T p.L327= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs779630479, COSV54777119, COSV54780939; called by muse, mutect2, varscan2
- POLR3E | c.2085C>T p.S695= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV55398855; called by muse, mutect2, varscan2
- PTPRC | c.2100C>T p.N700= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs200818686, COSV61406249; called by muse, mutect2, varscan2
- QPCTL | c.1026C>T p.I342= | Silent (SNP) | VAF 33/282 reads (12%) | catalogued as COSV99171245; called by muse, mutect2, varscan2
- RASL10B | c.474C>T p.C158= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- SERPIND1 | c.951G>A p.E317= | Silent (SNP) | VAF 26/314 reads (8%) | catalogued as rs756623445, COSV99300131; called by muse, mutect2
- SPEG | c.4194C>T p.I1398= | Silent (SNP) | VAF 27/258 reads (10%) | catalogued as rs767998262, COSV56671292, COSV56676919; called by muse, mutect2
- STIMATE-MUSTN1 | c.1026G>A p.S342= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs763855035, COSV56571223; called by muse, mutect2, varscan2
- TMPRSS7 | c.1188T>C p.C396= (on ENST00000452346; = p.C270= on NM_001042575.2) | Silent (SNP) | VAF 112/712 reads (16%) | catalogued as COSV69979522; called by muse, varscan2
- TREML2 | c.516C>G p.L172= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101530160, COSV72439215; called by muse, mutect2, varscan2
- TRIM37 | c.222A>G p.Q74= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs1446901610, COSV51881281; called by muse, mutect2, varscan2
- TTC13 | c.1389C>T p.H463= | Silent (SNP) | VAF 76/191 reads (40%) | catalogued as COSV64167714; called by muse, mutect2, varscan2
- TUBA4A | c.276C>T p.L92= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99944676, COSV99944715; called by muse, mutect2, varscan2
- YY2 | c.642G>A p.L214= | Silent (SNP) | VAF 10/229 reads (4%) | catalogued as COSV100810715; called by muse, mutect2
- ZNF569 | c.1821A>G p.E607= | Silent (SNP) | VAF 87/246 reads (35%) | catalogued as rs781212411, COSV57593451; called by muse, mutect2, varscan2
- ZNF883 | c.402C>T p.F134= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV101432543; called by muse, mutect2
- KIR3DX1 | n.731C>A | RNA (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99683192; called by muse, mutect2, varscan2
- ZNF658B | n.2058C>T | RNA (SNP) | VAF 124/532 reads (23%) | called by muse, mutect2
